Somatic mutation profile of tumor specimen TCGA-VS-A9UC-01A (aliquot TCGA-VS-A9UC-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 32.3 years (11,790 days).
Specimen TCGA-VS-A9UC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1cddad1-087f-489a-aa45-04ec429f2d5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UC-10A (Blood Derived Normal), aliquot TCGA-VS-A9UC-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/014c456f-1f92-4203-bbf4-a115b9c32ca8

The open-access MAF lists 186 somatic variants for this specimen: 141 protein-altering or splice-affecting, 40 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 40, Nonsense Mutation 20, Splice Region 2, Splice Site 2, Intron 2, Frame Shift Del 1, RNA 1, 5'UTR 1, 5'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF5 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 30/50 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66613960, COSV66613967; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 38/134 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- AACS | c.515C>G p.A172G | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV99907799; called by muse, mutect2, varscan2
- ADAM21 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99960599; called by muse, mutect2, varscan2
- ADAMTS5 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs1204827302, COSV99537119; called by mutect2, varscan2
- AGAP6 | c.900G>A p.M300I (on ENST00000374056 / NM_001365867.1; = p.M323I on NM_001077665.2) | Missense Mutation (SNP) | VAF 146/415 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as COSV100929047; called by muse, mutect2, varscan2
- AHSA1 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); catalogued as COSV99375855; called by muse, mutect2, varscan2
- AKT2 | c.1285C>T p.Q429* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100251435, COSV60907962; called by muse, mutect2, varscan2
- ANK1 | c.5572C>T p.P1858S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV99224200; called by muse, mutect2, varscan2
- ARHGAP32 | c.4970C>G p.S1657C (on ENST00000310343 / NM_001378025.1; = p.S1308C on NM_014715.4) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as COSV100087076; called by muse, mutect2, varscan2
- ATAD5 | c.5424G>C p.E1808D | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100035002; called by muse, mutect2, varscan2
- ATP7A | c.3451G>C p.D1151H | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.751); catalogued as COSV100430334; called by muse, mutect2, varscan2
- ATP8B2 | c.737G>A p.G246E (on ENST00000672630; = p.G213E on NM_001005855.2) | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100527690; called by muse, mutect2
- BEST2 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV99244255; called by muse, mutect2, varscan2
- BFAR | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as rs368858069, COSV99902038; called by muse, varscan2
- BOD1L1 | c.7235C>G p.S2412* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99238548; called by muse, mutect2, varscan2
- BUD31 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.856); catalogued as COSV99463259; called by muse, mutect2, varscan2
- CATSPER2 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV100390564; called by muse, mutect2, varscan2
- CIR1 | c.831T>A p.S277R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100564882; called by muse, mutect2, varscan2
- CLEC16A | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 79/160 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749052302, COSV68497981; called by muse, mutect2, varscan2
- COBLL1 | c.1960del p.E654Kfs*4 (on ENST00000392717; = p.E616Kfs*4 on NM_014900.5) | Frame Shift Del (DEL) | VAF 44/147 reads (30%) | catalogued as COSV52071951; called by mutect2, pindel, varscan2
- COL11A2 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as COSV59493194; called by muse, mutect2, varscan2
- CUL4B | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.367); catalogued as COSV100340210; called by muse, mutect2, varscan2
- CYFIP1 | c.3161A>T p.Y1054F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.223); catalogued as COSV100487845; called by muse, mutect2, varscan2
- CYLC2 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 38/122 reads (31%) | catalogued as COSV66336982, COSV66337374, COSV66339898; called by muse, mutect2, varscan2
- DAW1 | c.1051-1G>C p.X351_splice | Splice Site (SNP) | VAF 18/35 reads (51%) | catalogued as COSV100005900; called by muse, mutect2, varscan2
- DDAH2 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101007434; called by muse, mutect2, varscan2
- DHX29 | c.2190G>C p.L730F | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99287021; called by muse, varscan2
- DHX29 | c.2120G>C p.R707T | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52419651; called by muse, varscan2
- DNAJC13 | c.371C>G p.S124* | Nonsense Mutation (SNP) | VAF 69/300 reads (23%) | catalogued as COSV53446171, COSV99606732; called by muse, mutect2, varscan2
- E2F8 | c.987G>C p.K329N | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100001342; called by muse, mutect2, varscan2
- EBF3 | c.1374C>T p.V458= (on ENST00000355311 / NM_001375392.1; = p.V449= on NM_001005463.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 35/125 reads (28%) | catalogued as rs751553455, COSV100799071; called by muse, mutect2, varscan2
- EFCAB5 | c.1018A>G p.R340G | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs906546999, COSV100299851; called by muse, mutect2, varscan2
- EHHADH | c.1190C>G p.S397* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | catalogued as COSV99213106; called by muse, mutect2, varscan2
- EPHB2 | c.1299G>C p.Q433H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as COSV101006803; called by muse, mutect2, varscan2
- ERV3-1 | c.206C>G p.S69* | Nonsense Mutation (SNP) | VAF 27/81 reads (33%) | catalogued as COSV51429873, COSV99275240; called by muse, mutect2, varscan2
- ESCO2 | c.1544C>G p.S515C | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV100533131; called by muse, mutect2, varscan2
- F13A1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99070615, COSV99342361; called by muse, mutect2, varscan2
- FAHD1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1156682291, COSV101232490, COSV66900191; called by muse, mutect2, varscan2
- FAM120A | c.2287G>C p.D763H | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV52901843, COSV99464656; called by muse, mutect2
- FAM160B1 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 7/100 reads (7%) | catalogued as COSV100985307; called by muse, mutect2
- FCER1G | c.144C>T p.I48= | Splice Region (SNP) | VAF 34/110 reads (31%) | catalogued as rs1288089175, COSV99248107; called by muse, mutect2, varscan2
- FMO4 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 183/292 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100882030, COSV63000850; called by muse, mutect2, varscan2
- FUT4 | c.885G>A p.M295I | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100707995; called by muse, mutect2, varscan2
- GET3 | c.458+1G>C p.X153_splice | Splice Site (SNP) | VAF 18/35 reads (51%) | catalogued as COSV100628139; called by muse, mutect2, varscan2
- GIMAP4 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs778778849, COSV99750489; called by muse, varscan2
- GOLGB1 | c.7829C>G p.S2610C | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV61462591; called by muse, mutect2, varscan2
- GPAT4 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV101213882; called by muse, mutect2, varscan2
- GRID2 | c.2389A>G p.M797V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV99938097; called by muse, varscan2
- GRPR | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100977632; called by muse, mutect2
- HOXC10 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as COSV100329023; called by muse, mutect2
- HRNR | c.5705C>G p.S1902C | Missense Mutation (SNP) | VAF 38/835 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs767140543, COSV100913049; called by muse, mutect2
- HSF2BP | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.054); catalogued as rs1183217576, COSV99375100; called by muse, mutect2
- HTR3A | c.600G>C p.R200S | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs1349286450, COSV100248299; called by muse, mutect2, varscan2
- IGSF22 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs1179485343, COSV100079253; called by muse, mutect2, varscan2
- ILDR1 | c.1317C>G p.F439L (on ENST00000344209 / NM_001199799.2; = p.F395L on NM_175924.4) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99878004; called by muse, mutect2, varscan2
- ITGA9 | c.2551G>C p.E851Q | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.295); catalogued as COSV53245425, COSV99291821; called by muse, mutect2, varscan2
- IZUMO1R | c.379G>A p.E127K (on ENST00000440961; = p.E134K on NM_001199206.3) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100126820; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100583707; called by mutect2, varscan2
- JRKL | c.1498C>G p.L500V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as COSV99567102; called by muse, mutect2, varscan2
- KATNB1 | c.1730C>T p.T577M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11555150, COSV65550310; called by muse, mutect2, varscan2
- KMT2C | c.9209G>C p.R3070T | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100068076; called by muse, mutect2, varscan2
- KRT72 | c.498C>A p.N166K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.672); catalogued as COSV99537087; called by muse, mutect2, varscan2
- LAMA3 | c.5971G>C p.E1991Q (on ENST00000313654 / NM_198129.4; = p.E382Q on NM_000227.6) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.662); catalogued as COSV99334032; called by muse, mutect2, varscan2
- LCE3A | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.563); catalogued as COSV100175065; called by muse, mutect2, varscan2
- LEPR | c.2329C>G p.L777V | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100756347, COSV60755024; called by muse, mutect2
- LRRC18 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs753895079, COSV99628652; called by muse, mutect2, varscan2
- MAMLD1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99475586; called by muse, mutect2, varscan2
- MAP10 | c.1816C>T p.Q606* | Nonsense Mutation (SNP) | VAF 32/116 reads (28%) | catalogued as COSV101406440; called by muse, mutect2, varscan2
- MAST4 | c.719C>A p.S240* (on ENST00000403625 / NM_001164664.2; = p.S51* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 35/79 reads (44%) | catalogued as COSV99843107; called by muse, mutect2, varscan2
- MBD3 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as COSV99336859; called by muse, mutect2, varscan2
- MED24 | c.2724C>G p.I908M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as COSV99842308; called by muse, mutect2, varscan2
- MIEF1 | c.944C>G p.S315* | Nonsense Mutation (SNP) | VAF 7/107 reads (7%) | catalogued as COSV100307570; called by muse, mutect2
- MPHOSPH9 | c.2672C>G p.S891* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as COSV100186527; called by muse, mutect2, varscan2
- MPZL3 | c.9G>C p.Q3H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV99635024; called by muse, mutect2, varscan2
- MSH6 | c.654G>C p.K218N | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99315228; called by muse, mutect2
- MUC16 | c.5272C>T p.P1758S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs775021610, COSV101198414, COSV67486758; called by muse, mutect2, varscan2
- MYBPC2 | c.2639C>T p.P880L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs1409732986, COSV63093746; called by muse, mutect2
- MYT1L | c.2543C>T p.A848V | Missense Mutation (SNP) | VAF 85/151 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV101219169, COSV67730044; called by muse, mutect2, varscan2
- N4BP2 | c.4204C>G p.L1402V | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99788268; called by muse, mutect2, varscan2
- NAA20 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100131519; called by muse, mutect2, varscan2
- NAE1 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99322981; called by muse, mutect2, varscan2
- NFAT5 | c.1534C>G p.H512D | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV100590517; called by muse, mutect2, varscan2
- NFAT5 | c.3001C>T p.Q1001* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100590519; called by muse, mutect2, varscan2
- NOS3 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs765169676, COSV52486396, COSV52492850, COSV52495663; called by muse, mutect2, varscan2
- NRCAM | c.47G>C p.R16T | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV61030439, COSV61035172; called by muse, mutect2, varscan2
- NRXN2 | c.904C>G p.L302V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV55448189, COSV99632737; called by muse, mutect2, varscan2
- OR8D2 | c.569C>G p.S190C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV100658909; called by muse, mutect2, varscan2
- PDCD7 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as COSV99200125; called by muse, mutect2, varscan2
- PEG3 | c.3873C>A p.F1291L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.695); catalogued as COSV55631266, COSV99687637; called by muse, mutect2, varscan2
- PKDREJ | c.3333G>C p.Q1111H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99478489; called by muse, mutect2, varscan2
- PKHD1 | c.7939C>G p.P2647A | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV100581470; called by muse, mutect2
- PLEKHA7 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100850118; called by muse, mutect2
- PLEKHH3 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV99511803; called by muse, mutect2, varscan2
- PLXND1 | c.5481G>C p.E1827D | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.998); catalogued as COSV60721399; called by muse, varscan2
- PODN | c.1108C>T p.R370W (on ENST00000395871; = p.R322W on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs577667967, COSV100439363; called by muse, mutect2, varscan2
- PPP6R1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101336947; called by muse, mutect2
- PRTFDC1 | c.287C>G p.S96* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as COSV100196778; called by muse, mutect2, varscan2
- PTPRT | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.309); catalogued as COSV100625588; called by muse, mutect2, varscan2
- PUM1 | c.2306C>G p.S769C | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99927553, COSV99927704; called by muse, varscan2
- PUM1 | c.2242C>T p.L748F | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV99927554; called by muse, varscan2
- QRICH1 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100676686; called by muse, mutect2, varscan2
- RANBP3 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs748947507, COSV50381082; called by muse, mutect2, varscan2
- RBL2 | c.430C>G p.H144D | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1205772274, COSV100043358; called by muse, mutect2
- REM1 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV99146789, COSV99147101; called by muse, mutect2
- RGS13 | c.340C>G p.Q114E | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV101232202, COSV67346290; called by muse, mutect2, varscan2
- RIPPLY1 | c.401C>G p.S134* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as COSV99343597; called by muse, mutect2, varscan2
- RNF167 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.953); catalogued as COSV99337247; called by muse, mutect2, varscan2
- SACS | c.12228G>C p.L4076F | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV101207223; called by muse, mutect2
- SDHB | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100973331; called by muse, mutect2, varscan2
- SDK2 | c.2860C>T p.R954C | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs143950228; called by muse, mutect2, varscan2
- SEMA4A | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs780337679, COSV61772489; called by muse, mutect2, varscan2
- SETD5 | c.4126C>T p.Q1376* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100200241; called by muse, mutect2, varscan2
- SGSM1 | c.3446G>T p.*1149Lext*72 (on ENST00000400359 / NM_001039948.4; = p.*1088Lext*72 on NM_133454.3) | Nonstop Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV101240472; called by muse, mutect2, varscan2
- SIMC1 | c.1370G>A p.R457K (on ENST00000443967 / NM_001308196.1; = p.R476K on NM_001308195.2) | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.279); catalogued as rs1288842955, COSV100365257; called by muse, mutect2, varscan2
- SMG5 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.09); catalogued as rs1558240091, COSV100700718, COSV62434922; called by muse, mutect2, varscan2
- SMG7 | c.2290C>G p.L764V | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.063); catalogued as COSV100750110; called by muse, mutect2, varscan2
- SOS1 | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 40/311 reads (13%) | catalogued as COSV101216624; called by muse, mutect2, varscan2
- SOX12 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1188037724, COSV100705214; called by muse, mutect2, varscan2
- SOX4 | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1357457671, COSV99781936; called by muse, mutect2
- SRD5A3 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99947996; called by muse, mutect2, varscan2
- SREK1IP1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as rs1403024278, COSV101536166; called by muse, mutect2
- STON1 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100561551; called by muse, mutect2, varscan2
- TACC1 | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99393023; called by muse, mutect2
- THOC2 | c.3581G>A p.R1194K | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99832860; called by muse, mutect2, varscan2
- TLX1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756915239, COSV100930028; called by muse, mutect2, varscan2
- TMEM255B | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as rs199895059; called by muse, mutect2, varscan2
- TRPM4 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.439); catalogued as rs564940023, COSV99419139; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSGA10IP | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | catalogued as rs758452043, COSV73245228; called by muse, mutect2, varscan2
- TXLNA | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV65313792, COSV65314847; called by muse, mutect2, varscan2
- UBE2W | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1162394248, COSV100708674; called by muse, mutect2, varscan2
- UNC5C | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as COSV101497801; called by muse, mutect2, varscan2
- USP5 | c.2305G>A p.E769K (on ENST00000229268 / NM_001098536.2; = p.E746K on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.848); catalogued as COSV99978248; called by muse, mutect2, varscan2
- ZNF300 | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV99199798; called by muse, mutect2
- ZNF546 | c.2212C>G p.Q738E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV61256995; called by muse, mutect2, varscan2
- ZNF680 | c.1523A>T p.H508L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV100548972; called by muse, mutect2, varscan2
- ZNF711 | c.2206G>T p.E736* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV99340715; called by muse, mutect2, varscan2
- AKAP8L | c.327G>A p.M109I | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.075); called by muse, mutect2
- IGLV3-16 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2
- IRF7 | c.1487C>G p.S496C (on ENST00000397566; = p.S483C on NM_001572.5) | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- RTN4IP1 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2
- ADAMTS10 | c.3225C>G p.V1075= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV99546532; called by muse, mutect2, varscan2
- ADCY8 | c.2949G>A p.V983= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as COSV53900396; called by muse, mutect2, varscan2
- CA10 | c.180C>T p.C60= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as COSV99561870; called by muse, mutect2, varscan2
- CA6 | c.588G>C p.L196= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV101077401; called by muse, mutect2, varscan2
- CAPS2 | c.1137C>T p.L379= | Silent (SNP) | VAF 11/198 reads (6%) | catalogued as COSV100157404; called by muse, mutect2
- CEP76 | c.93C>T p.I31= | Silent (SNP) | VAF 42/130 reads (32%) | catalogued as COSV100042627; called by muse, mutect2, varscan2
- CIB2 | c.510G>A p.E170= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV99363108; called by muse, mutect2, varscan2
- CLCN5 | c.1272C>A p.V424= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100259846; called by muse, mutect2, varscan2
- COBL | c.1758C>T p.H586= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV99471515; called by muse, mutect2
- CREBRF | c.585C>A p.V195= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99755390; called by muse, mutect2, varscan2
- ENG | c.1065C>G p.L355= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV100785230; called by muse, mutect2, varscan2
- ENTR1 | c.366C>T p.L122= (on ENST00000357365 / NM_001039707.2; = p.L99= on NM_006643.4) | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV100048031; called by muse, mutect2, varscan2
- FLAD1 | c.759C>G p.L253= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV99422150; called by muse, mutect2
- HK3 | c.1230C>G p.L410= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV99457969; called by muse, mutect2, varscan2
- IGFN1 | c.3015G>A p.L1005= (on ENST00000295591 / NM_001367841.1; = p.L3462= on NM_001164586.2) | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- IGLV7-43 | c.333C>G p.L111= | Silent (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- IL12A | c.708C>T p.F236= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV59758995, COSV59760382; called by muse, mutect2, varscan2
- LSG1 | c.309C>G p.L103= | Silent (SNP) | VAF 34/45 reads (76%) | catalogued as COSV99503040; called by muse, mutect2, varscan2
- NBPF10 | c.1194C>G p.L398= | Silent (SNP) | VAF 8/153 reads (5%) | catalogued as rs1553794486, COSV61658033; called by muse, mutect2
- NES | c.2118G>A p.E706= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV100957764; called by muse, mutect2, varscan2
- NF1 | c.4122C>T p.H1374= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV100646178; called by muse, mutect2, varscan2
- NOP9 | c.81G>A p.G27= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99852186; called by muse, mutect2
- NR5A1 | c.213G>A p.Q71= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV101007643; called by muse, mutect2, varscan2
- OR4K17 | c.492G>A p.V164= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV100210537; called by muse, mutect2, varscan2
- P2RX2 | c.216G>C p.T72= (on ENST00000343948 / NM_170683.4; = p.G50R on NM_012226.5) | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV100265551; called by muse, mutect2, varscan2
- PEX1 | c.2019C>T p.V673= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99951918; called by muse, mutect2, varscan2
- PTGFRN | c.126C>T p.P42= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV101277260; called by muse, mutect2
- RNF122 | c.72G>A p.S24= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs755028263, COSV56359262; called by muse, mutect2
- SCD5 | c.696C>T p.L232= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV100124386; called by muse, mutect2, varscan2
- SLC47A2 | c.1713G>A p.V571= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV99449640; called by muse, mutect2
- SMARCC2 | c.1161C>T p.S387= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99910909; called by muse, mutect2, varscan2
- SPHKAP | c.3210G>C p.L1070= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100763765, COSV60888696; called by muse, mutect2, varscan2
- SSH2 | c.2775C>G p.L925= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99281530; called by muse, mutect2, varscan2
- TCFL5 | c.795C>T p.C265= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as rs1568797223, COSV99415596; called by muse, mutect2, varscan2
- TCTN1 | c.1722C>T p.I574= (on ENST00000551590 / NM_001173975.3; = p.I560= on NM_024549.6) | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV99657081; called by muse, mutect2
- TLL1 | c.400C>T p.L134= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99286402; called by muse, mutect2, varscan2
- TMEM245 | c.2639G>A p.*880= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV65822222; called by muse, mutect2, varscan2
- TMX2 | c.786G>A p.Q262= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV99559796; called by muse, mutect2, varscan2
- WNK2 | c.693C>T p.L231= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99941132; called by muse, mutect2, varscan2
- YY1AP1 | c.963G>A p.L321= (on ENST00000295566 / NM_139118.2; = p.L264= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/246 reads (12%) | catalogued as rs377332658, COSV55119905; called by muse, varscan2
- ARHGAP39 | c.2522-3522G>A | Intron (SNP) | VAF 32/105 reads (30%) | catalogued as COSV52766484; called by muse, mutect2, varscan2
- LDB2 | c.-1G>A | 5'UTR (SNP) | VAF 22/63 reads (35%) | catalogued as COSV100452745; called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516143 G>A | 5'Flank (SNP) | VAF 23/73 reads (32%) | catalogued as rs767211188, COSV99388931; called by muse, mutect2, varscan2
- TMEM167A | c.113+778G>A | Intron (SNP) | VAF 16/68 reads (24%) | catalogued as COSV101491861; called by muse, mutect2, varscan2
- TMEM183B | n.512C>T | RNA (SNP) | VAF 93/127 reads (73%) | called by muse, mutect2, varscan2
